MMRF case MMRF_1538 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6aa07ef6-e9cc-4850-87f3-ec14a387e1f6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.6 years (24,342 days); ISS stage: II; Days to last known disease status: 1,268 days (3.5 years); Days to last follow up: 1,268 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 2): M Protein 4.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 50.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 75.7 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 3.7 µg/mL; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.38 mmol/L; Albumin 33 g/L; Total Protein 12.4 g/dL; Glucose 7.48 mmol/L; C-Reactive Protein 12.6 mg/dL.
- Day 69 (ECOG 1): M Protein 0.2 g/dL; Immunoglobulin G 6.62 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.44 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 384 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 8.69 mmol/L.
- Day 169 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 5.85 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 8.53 mmol/L.
- Day 260 (ECOG 2): M Protein 0 g/dL; Immunoglobulin G 6.94 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 10.1 mmol/L.
- Day 363 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 8.09 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.5 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 8.8 mmol/L.
- Day 440 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.7 g/L; Hemoglobin 9.18 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 8.42 mmol/L.
- Day 538 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.75 g/L; Hemoglobin 9.61 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.53 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 6.27 mmol/L.
- Day 622 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.68 g/L; Hemoglobin 9.61 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.55 mmol/L; Albumin 42 g/L; Total Protein 7.8 g/dL; Glucose 6.16 mmol/L.
- Day 729 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.75 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 8.14 mmol/L.
- Day 816 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.75 g/L; Hemoglobin 9.98 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 8.1 g/dL; Glucose 10.7 mmol/L.
- Day 902 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.76 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 9.55 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.53 mmol/L; Albumin 42 g/L; Total Protein 8 g/dL; Glucose 11.3 mmol/L.
- Day 978 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.88 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 2.35 µg/mL; Hemoglobin 8.99 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 286 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 9.3 mmol/L.
- Day 1,268 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.76 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 9.55 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.53 mmol/L; Albumin 42 g/L; Total Protein 8 g/dL; Glucose 11.3 mmol/L.

Other clinical attributes
- Day -7: Weight: 117 kg; Height: 172 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1538_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_1538_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
